Somatic mutation profile of cancer-model specimen HCM-CSHL-0183-C25-85A (3D Organoid; aliquot HCM-CSHL-0183-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0183-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.0 years (23,374 days).
Specimen HCM-CSHL-0183-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da94d3f8-6fc1-4b96-90fa-f55eb336e2a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0183-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0183-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53c5f930-2b8c-427b-9401-9e03bf562f58

The open-access MAF lists 94 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Intron 7, 3'Flank 3, Frame Shift Del 2, 5'Flank 2, Nonsense Mutation 2, RNA 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 151/330 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 189/189 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs538139197, COSV67140479; called by muse, mutect2, varscan2
- ADCY8 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 310/849 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs753815200, COSV53913774; called by muse, mutect2, varscan2
- CAPN1 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1015587537; called by muse, mutect2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- ENOX2 | c.850C>T p.R284C (on ENST00000338144 / NM_001382520.1; = p.R255C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1391870850; called by muse, mutect2, varscan2
- FBXL7 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs771652620, COSV61647711; called by muse, mutect2, varscan2
- GPR32 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as rs767427575; called by muse, mutect2, varscan2
- GPR4 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV59916209, COSV59918028; called by muse, mutect2, varscan2
- HYDIN | c.2429A>G p.N810S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1017138844; called by mutect2, varscan2
- KAT8 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54899483; called by muse, mutect2, varscan2
- KCNK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 241/667 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57279943; called by muse, mutect2, varscan2
- KLHL25 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs374266297; called by muse, mutect2, varscan2
- LPIN1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 258/635 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as CD103916; called by muse, mutect2, varscan2
- NCOA3 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772403773, COSV59067229; called by muse, mutect2, varscan2
- NKAP | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65056547; called by muse, mutect2, varscan2
- NRXN1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as rs796052775, COSV68014124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCSK1N | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 197/578 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.942); catalogued as rs782526363; called by muse, mutect2, varscan2
- PDIA2 | c.1533G>A p.P511= | Splice Region (SNP) | VAF 52/132 reads (39%) | catalogued as rs571293134; called by muse, mutect2, varscan2
- PPP2R1B | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 178/372 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs888625399, COSV100232178, COSV59536995; called by muse, mutect2, varscan2
- PTPRK | c.3193C>T p.R1065W (on ENST00000368215 / NM_001291984.2; = p.R1066W on NM_002844.4) | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757577999, COSV100950250; called by muse, mutect2, varscan2
- RP1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 165/518 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV55114654, COSV55116485, COSV55120087; called by muse, mutect2, varscan2
- SH3GL1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 108/177 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as rs1460227872; called by muse, mutect2, varscan2
- SMAD4 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500743, COSV61683986, COSV61688959, COSV61693892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 138/321 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs377045177; called by muse, mutect2, varscan2
- TMEM63B | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs773890282, COSV99442126; called by muse, mutect2, varscan2
- TMPRSS11F | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as rs199559743, COSV100678692; called by muse, mutect2, varscan2
- TRIM75P | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs376399427; called by muse, mutect2
- WTIP | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs377447205; called by muse, mutect2, varscan2
- ZFHX4 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 43/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758193771, COSV50489578; called by muse, mutect2
- ZNF648 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 202/349 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60570840; called by muse, mutect2, varscan2
- ZNF777 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 133/234 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV56096557, COSV56098603; called by muse, mutect2, varscan2
- AL133500.1 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 174/413 reads (42%) | SIFT tolerated, low confidence (0.2); called by muse, mutect2, varscan2
- ARID1A | c.5089_5124+8del p.X1697_splice | Splice Site (DEL) | VAF 122/218 reads (56%) | called by mutect2, pindel
- ATP7A | c.767A>T p.K256M | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- BBS10 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- CNTNAP2 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP26C1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DEGS2 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAAP20 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM13A | c.465C>G p.D155E | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FCGR2C | c.359G>C p.S120T | Missense Mutation (SNP) | VAF 119/141 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGFR2 | c.2005T>C p.W669R | Missense Mutation (SNP) | VAF 232/565 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACE1 | c.48_61del p.R17Gfs*6 | Frame Shift Del (DEL) | VAF 155/165 reads (94%) | called by mutect2, pindel, varscan2
- HOXB1 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ILF3 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JAG1 | c.2872T>G p.C958G | Missense Mutation (SNP) | VAF 287/532 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF21B | c.2876G>C p.R959T | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAML2 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
- MINAR1 | c.1114A>G p.N372D | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PGBD5 | c.934C>A p.L312M (on ENST00000525115; = p.L381M on NM_001258311.2) | Missense Mutation (SNP) | VAF 13/380 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLR3H | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- RFTN1 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- SRSF8 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 143/367 reads (39%) | called by mutect2, pindel, varscan2
- TNS4 | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF746 | c.1474_1482del p.S492_G494del | In Frame Del (DEL) | VAF 57/163 reads (35%) | called by mutect2, pindel, varscan2
- ABRA | c.462C>T p.H154= | Silent (SNP) | VAF 149/387 reads (39%) | catalogued as rs546797793, COSV61733918; called by muse, mutect2, varscan2
- ADGRL2 | c.903G>A p.T301= | Silent (SNP) | VAF 98/456 reads (21%) | catalogued as rs1026759619, COSV54658246; called by muse, mutect2, varscan2
- AK1 | c.546C>A p.V182= | Silent (SNP) | VAF 217/449 reads (48%) | called by muse, mutect2, varscan2
- CAPN6 | c.1905C>T p.S635= | Silent (SNP) | VAF 99/200 reads (50%) | catalogued as rs921083346, COSV100137003; called by muse, mutect2, varscan2
- DCAF12L1 | c.141G>A p.T47= | Silent (SNP) | VAF 206/437 reads (47%) | catalogued as COSV64422083; called by muse, mutect2, varscan2
- DDOST | c.438G>C p.G146= (on ENST00000415136; = p.G129= on NM_005216.5) | Silent (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
- F13A1 | c.1878C>T p.T626= | Silent (SNP) | VAF 32/556 reads (6%) | catalogued as rs149970442; called by muse, mutect2
- KCNAB3 | c.90C>T p.G30= | Silent (SNP) | VAF 242/246 reads (98%) | catalogued as rs1268985172; called by muse, mutect2, varscan2
- KRT79 | c.384T>C p.H128= | Silent (SNP) | VAF 193/427 reads (45%) | catalogued as rs531448774; called by muse, mutect2, varscan2
- MBIP | c.582T>C p.C194= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- MUC12 | c.12735A>G p.E4245= (on ENST00000379442; = p.E4102= on NM_001164462.1) | Silent (SNP) | VAF 350/426 reads (82%) | called by muse, mutect2, varscan2
- MXRA5 | c.6471C>T p.D2157= | Silent (SNP) | VAF 95/229 reads (41%) | catalogued as rs1335154162; called by muse, mutect2, varscan2
- MYT1 | c.3183C>T p.S1061= | Silent (SNP) | VAF 104/252 reads (41%) | catalogued as rs1273170188, COSV60501160; called by muse, mutect2, varscan2
- OR1A1 | c.723T>C p.G241= | Silent (SNP) | VAF 79/79 reads (100%) | called by muse, mutect2, varscan2
- PCDH15 | c.1317A>G p.P439= | Silent (SNP) | VAF 224/439 reads (51%) | catalogued as rs768151894; called by muse, mutect2, varscan2
- PCDHA3 | c.213C>T p.H71= | Silent (SNP) | VAF 552/622 reads (89%) | catalogued as rs138112183, COSV65366172; called by muse, varscan2
- RASIP1 | c.2349T>A p.L783= | Silent (SNP) | VAF 7/192 reads (4%) | called by muse, mutect2
- RSPH10B2 | c.189C>T p.N63= | Silent (SNP) | VAF 247/859 reads (29%) | catalogued as rs753432937; called by muse, mutect2, varscan2
- SPTBN5 | c.4314C>T p.L1438= | Silent (SNP) | VAF 113/197 reads (57%) | catalogued as rs762819167, COSV58028988; called by muse, mutect2, varscan2
- TBKBP1 | c.21C>T p.D7= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as rs373991355; called by muse, mutect2, varscan2
- TGFBR2 | c.9G>A p.R3= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1559443648; ClinVar: likely benign; called by muse, mutect2
- VPS13C | c.5877A>T p.G1959= (on ENST00000644861 / NM_020821.3; = p.G1916= on NM_017684.5) | Silent (SNP) | VAF 96/156 reads (62%) | called by muse, varscan2
- AC024651.2 | chr15:97874219 C>T | 5'Flank (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- AC103996.1 | chr15:93821050 T>A | 3'Flank (SNP) | VAF 144/366 reads (39%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500844 del GGG | 5'Flank (DEL) | VAF 80/194 reads (41%) | catalogued as rs772360578; called by mutect2, pindel, varscan2
- DAW1 | c.973+5183A>G | Intron (SNP) | VAF 120/219 reads (55%) | called by muse, mutect2, varscan2
- EGFR | c.1881-2631C>G | Intron (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- FAM90A27P | n.1231C>T | RNA (SNP) | VAF 60/258 reads (23%) | called by muse, mutect2
- FNTA | c.783-12_783-11insA | Intron (INS) | VAF 24/106 reads (23%) | called by pindel, varscan2
- MDGA2 | c.281-41435G>T | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- MED13L | c.2238+20_2238+21insGG | Intron (INS) | VAF 102/334 reads (31%) | called by pindel, varscan2
- MIR154 | n.13G>A | RNA (SNP) | VAF 134/342 reads (39%) | called by muse, mutect2, varscan2
- MIR6511A1 | chr16:14929398 A>G | 3'Flank (SNP) | VAF 367/1578 reads (23%) | catalogued as rs528377283; called by muse, mutect2, varscan2
- PLEKHS1 | chr10:113780764 del AAAGGAGCCAGGGAGT | 3'Flank (DEL) | VAF 20/146 reads (14%) | called by mutect2, pindel
- TXNRD1 | c.415-1272T>G | Intron (SNP) | VAF 135/301 reads (45%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-3383A>G | Intron (SNP) | VAF 114/253 reads (45%) | catalogued as rs891088251; called by muse, mutect2, varscan2
